Gene-level copy-number profile of tumor specimen TCGA-DA-A3F5-06A from TCGA case TCGA-DA-A3F5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.2 years (22,720 days).
Specimen TCGA-DA-A3F5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.2b8feb0f-a135-4946-af95-8d6d9debc53f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A3F5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06f715fc-2354-425a-a2df-39e9c7fa0d89

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 18; copy number 2: 7,935; copy number 3: 18,536; copy number 4: 9,100; copy number 5: 8,774; copy number 6: 9,914; copy number 7: 2,691; copy number 8: 827; copy number 10: 994; copy number 11: 410; copy number 12: 363; copy number 13: 168; copy number 51: 16; copy number 58: 7; copy number 62: 31; copy number 63: 1; copy number 68: 19; copy number 94: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A3F5-06A-11D-A20B-01): tumor purity 0.44, ploidy 3.98, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,002,903–22,012,536, 2 genes (within-gene range 0–5): CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,535 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,302,889–10,457,693, 4 genes, copy number 8 (within-gene range 5–8): HPCAL1, ODC1, SNORA80B, ODC1-DT.
- chr2:139,668,547–140,221,485, 8 genes, copy number 7: MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,683,888, 3 genes, copy number 7: AC092156.1, MIR7157, COPRSP1.
- chr3:61,561,569–90,261,708, 277 genes, copy number 8 (broad region; genes not listed).
- chr4:49,096–62,818,794, 907 genes, copy number 7–8 (broad region; genes not listed).
- chr5:58,198–4,147,429, 95 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:63,011,463–159,233,377, 1,935 genes, copy number 10–13 (broad region; genes not listed).
- chr8:2,130,550–139,127,953, 2,224 genes, copy number 7 (broad region; genes not listed).
- chr15:73,051,710–73,889,214, 16 genes, copy number 51: NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2, REC114, MRPS15P1, NPTN, NPTN-IT1, CD276, AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21.
- chr15:75,452,964–76,905,444, 40 genes, copy number 62–94 (within-gene range 4–94): AC105137.2, PTPN9, AC105036.2, AC105036.1, AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22, NRG4, AC027104.1, TMEM266, AC091100.1, ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1.
- chr15:76,976,915–77,820,900, 19 genes, copy number 68: RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr15:96,438,570–96,551,517, 7 genes, copy number 58: AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
